Somatic mutation profile of tumor specimen MP2PRT-PANVLH-TMP1-A (aliquot MP2PRT-PANVLH-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANVLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (720 days).
Specimen MP2PRT-PANVLH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74961975-7b78-4219-a5e8-c1dfd679fc08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVLH-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ec698f6-62b0-4bac-8dbb-f260eecbd4ec

The open-access MAF lists 57 somatic variants for this specimen: 36 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 19, Nonsense Mutation 3, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1575G>C p.L525F (on ENST00000288602 / NM_001374244.1; = p.L485F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs180177036, CM060880, COSV56396779; ClinVar: pathogenic; called by muse, mutect2
- ACP3 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 20/465 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1408124009; called by muse, mutect2
- ADGB | c.4443G>C p.L1481F | Missense Mutation (SNP) | VAF 125/420 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58848712; called by muse, mutect2, varscan2
- ARHGEF11 | c.4153C>G p.Q1385E | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.079); catalogued as COSV59356344; called by muse, mutect2
- BBS7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV52654200; called by muse, mutect2, varscan2
- BTBD9 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.303); catalogued as rs769629568; called by muse, mutect2, varscan2
- C10orf90 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV52957491, COSV52958261; called by muse, mutect2
- CBLC | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 94/922 reads (10%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.503); catalogued as rs749090451; called by muse, mutect2, varscan2
- GRID2 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99936828; called by muse, mutect2
- KIAA0825 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100265973; called by muse, mutect2, varscan2
- LEPR | c.2784G>T p.W928C | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as COSV62748114; called by muse, mutect2
- MAGI1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.205); catalogued as rs1399969062; called by muse, mutect2, varscan2
- MORN4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100167440; called by muse, mutect2, varscan2
- PMM1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.989); catalogued as rs376315549, COSV99348086; called by muse, varscan2
- PRRC2C | c.5441C>G p.S1814* (on ENST00000367742; = p.S1812* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 21/765 reads (3%) | catalogued as COSV100145319, COSV58903667; called by muse, mutect2
- RAD54B | c.2120A>G p.N707S | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs138037330; called by muse, mutect2, varscan2
- TACSTD2 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 72/640 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs567649208; called by muse, mutect2, varscan2
- TGFBR2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV55447413, COSV55458911; called by muse, mutect2
- ZDHHC20 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as rs1472706047, COSV57186263; called by muse, mutect2, varscan2
- ZNF579 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 92/808 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV57637934; called by muse, mutect2
- CNRIP1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CYLC2 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- HERC2 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 151/441 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- HOOK1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2
- KIF27 | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2
- MAGI1 | c.4023G>C p.E1341D | Missense Mutation (SNP) | VAF 69/656 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- MTURN | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- NUP58 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 34/300 reads (11%) | called by muse, mutect2, varscan2
- PIP4P1 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLCB1 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PSMB5 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 32/317 reads (10%) | called by muse, mutect2, varscan2
- SYCP2L | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TOR1AIP1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 77/604 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS54 | c.1905C>G p.F635L | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZCCHC9 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ZSCAN5A | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 66/662 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); called by muse, mutect2
- A2M | c.3261C>G p.L1087= | Silent (SNP) | VAF 26/283 reads (9%) | called by muse, mutect2
- CACNA2D3 | c.2418C>G p.L806= | Silent (SNP) | VAF 49/340 reads (14%) | catalogued as COSV99878157; called by muse, mutect2, varscan2
- CUX2 | c.3147G>A p.T1049= | Silent (SNP) | VAF 165/517 reads (32%) | catalogued as rs757600625, COSV55636299; called by muse, mutect2, varscan2
- DIPK1B | c.855C>T p.L285= | Silent (SNP) | VAF 18/663 reads (3%) | called by muse, mutect2
- GPR89B | c.1134C>G p.V378= | Silent (SNP) | VAF 18/311 reads (6%) | called by muse, mutect2
- IBTK | c.2877C>T p.F959= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1189C>T p.L397= | Silent (SNP) | VAF 12/344 reads (3%) | called by muse, mutect2
- KIFC1 | c.1734C>T p.L578= | Silent (SNP) | VAF 103/949 reads (11%) | catalogued as rs774299603, COSV65729299; called by muse, mutect2, varscan2
- MBOAT1 | c.1254C>G p.L418= | Silent (SNP) | VAF 40/502 reads (8%) | catalogued as rs946261836; called by muse, mutect2
- NAGS | c.1604G>A p.*535= | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as COSV52813650; called by muse, mutect2
- NLGN1 | c.192G>A p.G64= | Silent (SNP) | VAF 49/513 reads (10%) | catalogued as rs1560037189, COSV64336714; called by muse, mutect2, varscan2
- NTN1 | c.108G>A p.A36= | Silent (SNP) | VAF 124/966 reads (13%) | called by muse, mutect2, varscan2
- PIP4P1 | c.231G>T p.G77= | Silent (SNP) | VAF 60/651 reads (9%) | catalogued as COSV99164448; called by muse, mutect2
- POGLUT1 | c.441C>G p.V147= | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- S1PR4 | c.79C>T p.L27= | Silent (SNP) | VAF 28/885 reads (3%) | called by muse, mutect2
- SH3GL2 | c.618G>A p.E206= | Silent (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- SLITRK1 | c.537C>T p.I179= | Silent (SNP) | VAF 26/508 reads (5%) | catalogued as COSV65674795; called by muse, mutect2
- TTC34 | c.1131C>G p.L377= | Silent (SNP) | VAF 88/898 reads (10%) | called by muse, mutect2
- UBE4B | c.1068C>T p.L356= | Silent (SNP) | VAF 74/692 reads (11%) | catalogued as rs758645417, COSV53531997; called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1813G>A | Intron (SNP) | VAF 24/647 reads (4%) | catalogued as rs1031091412; called by muse, mutect2
- WNK2 | chr9:93319143 C>T | 3'Flank (SNP) | VAF 26/334 reads (8%) | catalogued as rs746205595; called by muse, mutect2
